Somatic mutation profile of cancer-model specimen HCM-SANG-0312-C15-85A (3D Organoid; aliquot HCM-SANG-0312-C15-85A-01D-A78M-36), derived from the primary tumor of HCMI case HCM-SANG-0312-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0312-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9add546-8492-4927-ab0b-1dd8b4af4360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0312-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0312-C15-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b9955e3-dfff-4291-b071-b74298cc6036

The open-access MAF lists 239 somatic variants for this specimen: 153 protein-altering or splice-affecting, 55 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 55, Intron 14, Nonsense Mutation 10, Frame Shift Del 7, 5'UTR 5, 3'UTR 5, RNA 4, 5'Flank 3, Splice Region 3, Splice Site 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 139/290 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 127/280 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs138587496; called by muse, mutect2, varscan2
- ADGRB1 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.668); catalogued as rs765301142; called by muse, mutect2, varscan2
- ADGRF5 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs754646677, COSV99344947; called by muse, mutect2, varscan2
- AFF2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 92/92 reads (100%) | catalogued as COSV53988097; called by muse, varscan2
- AMOTL1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.098); catalogued as rs371806495, COSV54414848; called by muse, mutect2, varscan2
- AP5M1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs753766525; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 239/473 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs199650259, COSV59480388; called by muse, mutect2, varscan2
- B4GALNT4 | c.3107C>T p.T1036M | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs781281268, COSV57322761; called by muse, mutect2, varscan2
- BRAF | c.2132G>A p.R711Q (on ENST00000288602 / NM_001374244.1; = p.R671Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs397507485, COSV56226275, COSV99967384; called by muse, mutect2, varscan2
- CDH10 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52584543, COSV52586176; called by muse, mutect2, varscan2
- CDH5 | c.1340C>G p.A447G | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58519424; called by muse, mutect2, varscan2
- CNTLN | c.2473A>G p.M825V | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs762347545, COSV52099071; called by muse, mutect2, varscan2
- CNTNAP1 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52849296; called by muse, mutect2, varscan2
- CNTNAP4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145844553; called by muse, mutect2, varscan2
- COL22A1 | c.3511G>T p.G1171* | Nonsense Mutation (SNP) | VAF 111/244 reads (45%) | catalogued as COSV57332567; called by muse, mutect2, varscan2
- CUX2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs771675208, COSV55638590; called by muse, mutect2, varscan2
- DENND4A | c.4688G>A p.R1563Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs746530544; called by muse, mutect2, varscan2
- DPYS | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1336530598; called by muse, mutect2, varscan2
- DROSHA | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs756470214; called by muse, mutect2, varscan2
- FBLN1 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 358/714 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1040114477, COSV99410868; called by muse, mutect2, varscan2
- FCGBP | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 156/294 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.331); catalogued as rs1297465608; called by muse, mutect2, varscan2
- FERMT1 | c.618C>G p.F206L | Missense Mutation (SNP) | VAF 206/446 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.731); catalogued as COSV54093379; called by muse, mutect2, varscan2
- FLG | c.2671A>G p.S891G | Missense Mutation (SNP) | VAF 278/581 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100910462, COSV64239905; called by muse, mutect2, varscan2
- FNIP2 | c.1232A>C p.N411T | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV52436994; called by muse, mutect2, varscan2
- FSCB | c.945A>C p.K315N | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV61218952, COSV61219385; called by muse, mutect2, varscan2
- GRIA3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 95/95 reads (100%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.682); catalogued as rs1392959973, COSV52063686; called by muse, mutect2, varscan2
- GRM5 | c.1801T>A p.F601I | Missense Mutation (SNP) | VAF 173/264 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59589976; called by muse, mutect2, varscan2
- GSTA3 | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV52980581; called by muse, mutect2, varscan2
- HDGFL1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 184/364 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57751916; called by muse, mutect2, varscan2
- IFT122 | c.2885C>T p.T962M (on ENST00000348417 / NM_052989.3; = p.T903M on NM_018262.4) | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs758067204; called by muse, mutect2, varscan2
- IKBKG | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.047); catalogued as COSV100852984; called by muse, mutect2, varscan2
- IRF6 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 64/289 reads (22%) | catalogued as CM092364, COSV99671125; called by muse, mutect2, varscan2
- IRS2 | c.2611C>T p.R871W | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1446914389; called by muse, mutect2
- KCNK13 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs888123272; called by muse, mutect2, varscan2
- KIR2DL4 | c.1153G>A p.E385K (on ENST00000396284; = p.E311K on NM_001080770.2) | Missense Mutation (SNP) | VAF 226/576 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); catalogued as rs1164138861; called by muse, mutect2, varscan2
- LYST | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs971416672; called by muse, mutect2, varscan2
- MCM5 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99331411; called by muse, mutect2, varscan2
- MDGA2 | c.1939T>G p.L647V (on ENST00000399232 / NM_001113498.2; = p.L349V on NM_182830.4) | Missense Mutation (SNP) | VAF 208/412 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.23); catalogued as COSV100636432; called by muse, mutect2, varscan2
- MRPS27 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as rs779544739; called by muse, mutect2, varscan2
- NOS1 | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs759876695; called by muse, mutect2, varscan2
- OPRD1 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1333370003; called by muse, mutect2, varscan2
- OR10G9 | c.512A>C p.N171T | Missense Mutation (SNP) | VAF 252/411 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV66686661; called by muse, mutect2, varscan2
- OR1A1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58404831; called by muse, mutect2, varscan2
- OR2T2 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 242/853 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100737874; called by muse, mutect2, varscan2
- OSBPL10 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 78/145 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs754570919, COSV67339615; called by muse, mutect2, varscan2
- PCDHA1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 102/552 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV65376184; called by muse, mutect2, varscan2
- PCDHB8 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 196/983 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.458); catalogued as rs147143495; called by muse, mutect2, varscan2
- PLXDC2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 130/277 reads (47%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs137878669; called by muse, mutect2, varscan2
- POM121L12 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.988); catalogued as rs867265387; called by muse, mutect2
- PROSER3 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); catalogued as rs989084164; called by muse, mutect2
- PSAP | c.1314A>T p.K438N | Missense Mutation (SNP) | VAF 28/595 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99819969; called by muse, mutect2
- PTPRT | c.2468G>A p.S823N | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as rs766051611; called by muse, mutect2, varscan2
- PTPRT | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100629312, COSV61960741; called by muse, mutect2, varscan2
- RASD2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 38/441 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs773539958; called by muse, mutect2
- ROBO2 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165056, COSV59894479; called by muse, mutect2, varscan2
- RORB | c.230G>A p.R77Q (on ENST00000396204 / NM_001365023.1; = p.R66Q on NM_006914.4) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756765022, COSV100974200; called by muse, mutect2, varscan2
- RYR3 | c.9774C>A p.C3258* (on ENST00000389232; = p.C3259* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 113/219 reads (52%) | catalogued as COSV66811417; called by muse, mutect2, varscan2
- SCNN1A | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 193/404 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs529383103; called by muse, mutect2, varscan2
- SDK2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 128/262 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.378); catalogued as rs574582614, COSV66187387; called by muse, mutect2, varscan2
- SEMA4F | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs750930854; called by muse, mutect2, varscan2
- SERGEF | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 109/252 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs758465478, COSV56384929; called by muse, mutect2, varscan2
- TAOK1 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 40/116 reads (34%) | catalogued as COSV99913944; called by muse, mutect2, varscan2
- TBXAS1 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 69/761 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs372058761, COSV54945453; called by muse, mutect2
- TENM2 | c.1138G>A p.A380T (on ENST00000518659 / NM_001122679.2; = p.A189T on NM_001080428.3) | Missense Mutation (SNP) | VAF 113/215 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs751197197; called by muse, mutect2, varscan2
- TH | c.789-5C>T | Splice Region (SNP) | VAF 111/206 reads (54%) | catalogued as rs755960694; called by muse, mutect2, varscan2
- TNN | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs759170212; called by muse, mutect2, varscan2
- TOGARAM1 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV61888733; called by muse, mutect2, varscan2
- TRAPPC12 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 190/402 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs138265331, COSV100160379; called by muse, mutect2, varscan2
- TTC21B | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs370484375; called by muse, mutect2, varscan2
- TUBGCP6 | c.3352G>A p.G1118R | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574080138, COSV50536188; called by muse, mutect2, varscan2
- UCHL1 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 237/509 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs764784241, COSV52653531; called by muse, mutect2, varscan2
- USH2A | c.13226C>T p.S4409F | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as rs752003063, COSV56415746; called by muse, mutect2, varscan2
- WSCD1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs769801984, COSV58495317; called by muse, mutect2, varscan2
- ZNF99 | c.2004A>C p.K668N | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV68055472; called by muse, mutect2, varscan2
- ABCA7 | c.2048_2067+11del p.X683_splice | Splice Site (DEL) | VAF 31/136 reads (23%) | called by mutect2, pindel
- ADAMTS19 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ANKRD30B | c.3592A>T p.N1198Y | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ASTN1 | c.3719A>G p.K1240R | Missense Mutation (SNP) | VAF 126/254 reads (50%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP10B | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ATRNL1 | c.3810A>C p.E1270D | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- BMPER | c.1955T>G p.I652S | Missense Mutation (SNP) | VAF 142/348 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CBX8 | c.910_920del p.G304Pfs*50 | Frame Shift Del (DEL) | VAF 27/174 reads (16%) | called by mutect2, pindel, varscan2
- CELF3 | c.604G>T p.G202* | Nonsense Mutation (SNP) | VAF 74/164 reads (45%) | called by muse, mutect2, varscan2
- CSMD3 | c.3041G>T p.G1014V (on ENST00000297405 / NM_001363185.1; = p.G910V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CUX2 | c.4286del p.P1429Lfs*23 | Frame Shift Del (DEL) | VAF 81/190 reads (43%) | called by mutect2, pindel, varscan2
- DNAH10 | c.12331G>A p.E4111K (on ENST00000409039; = p.E4050K on NM_207437.3) | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DNAH11 | c.8993A>C p.K2998T | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH7 | c.3846A>C p.K1282N | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DNMT3B | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 198/444 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DPH1 | c.1228-3C>G | Splice Region (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- E4F1 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- EPHA4 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2
- EVC2 | c.2103G>T p.E701D | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- FAM135B | c.1921T>C p.C641R | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM20C | c.470A>T p.D157V | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAT1 | c.8576C>A p.S2859Y | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FGG | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FUCA2 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 48/78 reads (62%) | called by muse, varscan2
- FXYD2 | c.161del p.G54Afs*65 | Frame Shift Del (DEL) | VAF 69/493 reads (14%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 186/672 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, varscan2
- IGHV2-26 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IGSF21 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 230/388 reads (59%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.992); called by muse, varscan2
- IL27RA | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 8/231 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL9R | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IMPG2 | c.3068C>T p.S1023L | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IRAK1 | c.1264A>T p.R422W | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRF6 | c.1211A>T p.E404V | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRS4 | c.3169G>C p.D1057H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- JAK2 | c.2207_2208del p.K736Mfs*16 | Frame Shift Del (DEL) | VAF 24/33 reads (73%) | called by mutect2, pindel, varscan2
- KCNG1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KIF4A | c.3304C>A p.Q1102K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KMT2B | c.3550G>A p.V1184M | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRATD2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- MAFG | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 64/290 reads (22%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2915G>C p.G972A | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MAST4 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.16150A>G p.S5384G | Missense Mutation (SNP) | VAF 110/231 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MUC6 | c.5013G>A p.M1671I | Missense Mutation (SNP) | VAF 132/1222 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- MYLK3 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NRG1 | c.40C>A p.L14M (on ENST00000523534; = p.L161M on NM_013962.2) | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR13C3 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); called by muse, mutect2
- OR1C1 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T6 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PADI3 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2236_2237del p.T746Afs*36 (on ENST00000259318 / NM_001136562.3; = p.T977Afs*36 on NM_007203.5) | Frame Shift Del (DEL) | VAF 17/120 reads (14%) | called by mutect2, pindel, varscan2
- PCNX4 | c.3464C>A p.P1155H (on ENST00000406854 / NM_001330177.2; = p.P921H on NM_022495.5) | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PEX12 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLCL1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.101); called by muse, mutect2
- PLOD2 | c.2214A>C p.*738Yext*8 | Nonstop Mutation (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- PTPRM | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SDK1 | c.5408G>T p.G1803V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SHISA9 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC17A2 | c.689T>A p.V230E | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2
- SOGA1 | c.3452A>T p.E1151V | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPTA1 | c.5962A>G p.I1988V | Missense Mutation (SNP) | VAF 234/465 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SRRM1 | c.922T>C p.S308P | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SSH2 | c.290_293del p.E97Vfs*11 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | called by mutect2, pindel, varscan2
- SZT2 | c.7919C>T p.S2640L (on ENST00000634258 / NM_001365999.1; = p.S2583L on NM_015284.4) | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX22 | c.1237T>G p.L413V | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM213 | c.154+3A>T | Splice Region (SNP) | VAF 57/262 reads (22%) | called by muse, mutect2, varscan2
- TMEM50B | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.309); called by muse, mutect2
- TNFRSF10B | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.55712_55713del p.Q18571Rfs*16 (on ENST00000591111; = p.Q11147Rfs*16 on NM_003319.4) | Frame Shift Del (DEL) | VAF 28/63 reads (44%) | called by mutect2, pindel, varscan2
- TTN | c.32422G>T p.E10808* (on ENST00000591111; = p.E9881* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 49/162 reads (30%) | called by muse, mutect2, varscan2
- UQCRFS1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- USP24 | c.6617G>C p.C2206S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- VPS8 | c.1267A>G p.K423E (on ENST00000625842 / NM_001349294.1; = p.K421E on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- WDFY4 | c.3752T>G p.V1251G | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZBTB7B | c.632C>T p.T211I (on ENST00000292176; = p.T245I on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF138 | c.635A>C p.K212T (on ENST00000307355 / NM_001367572.1; = p.K186T on NM_006524.4) | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.03); called by muse, mutect2
- ZNF213 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- ZSWIM8 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 28/189 reads (15%) | called by muse, mutect2, varscan2
- ACSM1 | c.564G>T p.V188= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as rs1216747230; called by muse, mutect2
- ASCL4 | c.69C>T p.G23= | Silent (SNP) | VAF 29/402 reads (7%) | catalogued as COSV60816239; called by muse, mutect2
- ATP10A | c.546G>C p.L182= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as COSV63514109; called by muse, mutect2
- C3orf56 | c.555C>T p.A185= | Silent (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- CCDC69 | c.663G>A p.Q221= | Silent (SNP) | VAF 86/206 reads (42%) | called by muse, mutect2, varscan2
- CDH8 | c.1128G>A p.A376= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs369487557; called by muse, mutect2
- CHD5 | c.5667C>T p.A1889= | Silent (SNP) | VAF 89/131 reads (68%) | catalogued as rs768719057, COSV52421873; called by muse, mutect2, varscan2
- CYLC1 | c.1707G>A p.K569= | Silent (SNP) | VAF 34/34 reads (100%) | called by muse, mutect2, varscan2
- DOK4 | c.585C>G p.T195= | Silent (SNP) | VAF 18/496 reads (4%) | called by muse, mutect2
- DYSF | c.5748C>T p.F1916= | Silent (SNP) | VAF 151/335 reads (45%) | catalogued as COSV99244008; called by muse, mutect2, varscan2
- EBF1 | c.1137C>T p.L379= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- EMILIN2 | c.345G>A p.G115= | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- FAM135B | c.2820G>A p.T940= | Silent (SNP) | VAF 88/167 reads (53%) | catalogued as rs529502221; called by muse, mutect2, varscan2
- FBN2 | c.4437C>A p.G1479= | Silent (SNP) | VAF 241/550 reads (44%) | called by muse, mutect2, varscan2
- GNA15 | c.9C>T p.R3= | Silent (SNP) | VAF 13/171 reads (8%) | catalogued as rs1292963881; called by muse, mutect2
- GOT2 | c.735C>T p.A245= | Silent (SNP) | VAF 103/218 reads (47%) | called by muse, mutect2, varscan2
- GTDC1 | c.651T>C p.N217= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs370029984; called by muse, mutect2, varscan2
- HLA-DQB2 | c.195C>T p.Y65= | Silent (SNP) | VAF 137/346 reads (40%) | catalogued as rs751869503, COSV101370041; called by muse, mutect2, varscan2
- HRNR | c.780C>T p.H260= | Silent (SNP) | VAF 258/549 reads (47%) | catalogued as rs139159585, COSV64256801; called by muse, mutect2, varscan2
- HSPA6 | c.1296C>A p.T432= | Silent (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- ISM2 | c.336G>T p.L112= | Silent (SNP) | VAF 151/372 reads (41%) | called by muse, mutect2, varscan2
- KCNV1 | c.297C>T p.N99= | Silent (SNP) | VAF 28/502 reads (6%) | catalogued as COSV52086110; called by muse, mutect2
- MARCHF11 | c.531G>A p.A177= | Silent (SNP) | VAF 96/192 reads (50%) | catalogued as rs1410761971, COSV60126788; called by muse, mutect2, varscan2
- MLH3 | c.618C>T p.D206= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs762968546; called by muse, mutect2, varscan2
- MUC17 | c.15G>A p.G5= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as COSV59331525, COSV59332200; called by muse, mutect2, varscan2
- MYOM2 | c.987G>A p.T329= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs771981018, COSV50707184; called by muse, mutect2, varscan2
- NCAPD3 | c.4137T>G p.T1379= | Silent (SNP) | VAF 76/109 reads (70%) | called by muse, mutect2, varscan2
- NLGN4Y | c.1161G>A p.E387= | Silent (SNP) | VAF 171/230 reads (74%) | called by muse, mutect2, varscan2
- NUTM1 | c.543G>A p.G181= | Silent (SNP) | VAF 116/201 reads (58%) | called by muse, mutect2, varscan2
- OBSCN | c.11337C>T p.A3779= | Silent (SNP) | VAF 94/377 reads (25%) | catalogued as rs370393148; called by muse, mutect2, varscan2
- OR10K1 | c.552C>T p.V184= | Silent (SNP) | VAF 62/124 reads (50%) | called by muse, mutect2, varscan2
- OR2L13 | c.354C>G p.A118= | Silent (SNP) | VAF 32/382 reads (8%) | catalogued as COSV100813808; called by muse, mutect2
- PCDHA4 | c.1725C>T p.G575= | Silent (SNP) | VAF 200/388 reads (52%) | catalogued as rs538609667, COSV63546083; called by muse, mutect2, varscan2
- PKNOX2 | c.243G>A p.P81= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs758344216, COSV53544311; called by muse, mutect2
- PLCL1 | c.996C>A p.A332= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- PLCL1 | c.1915T>C p.L639= | Silent (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- PNPLA6 | c.123C>T p.G41= | Silent (SNP) | VAF 21/356 reads (6%) | called by muse, mutect2
- PROSER2 | c.939G>A p.P313= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- PTPRN2 | c.270C>T p.S90= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs202155029; ClinVar: likely benign; called by muse, mutect2, varscan2
- PXN | c.594G>A p.T198= | Silent (SNP) | VAF 42/277 reads (15%) | catalogued as rs1320665138, COSV57218390; called by muse, mutect2, varscan2
- SCAPER | c.1473C>T p.N491= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs770079137; called by muse, mutect2, varscan2
- SERPINA7 | c.907T>C p.L303= | Silent (SNP) | VAF 96/96 reads (100%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.816G>A p.R272= (on ENST00000308713 / NM_001114099.3; = p.R202= on NM_012410.4) | Silent (SNP) | VAF 79/160 reads (49%) | called by muse, mutect2, varscan2
- SKA1 | c.633A>T p.I211= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2
- SLC35F3 | c.339G>A p.P113= (on ENST00000366617 / NM_001300845.1; = p.P182= on NM_173508.4) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs374911955; called by muse, mutect2
- SLC6A5 | c.489G>A p.T163= | Silent (SNP) | VAF 167/307 reads (54%) | catalogued as rs145813913; called by muse, mutect2, varscan2
- SSU72P8 | c.363A>G p.E121= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- SYNE1 | c.15414G>A p.A5138= (on ENST00000367255 / NM_182961.4; = p.A5067= on NM_033071.3) | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as rs746436040, COSV54954838; called by muse, mutect2, varscan2
- SYT3 | c.1641C>T p.R547= | Silent (SNP) | VAF 117/250 reads (47%) | catalogued as rs1431914047; called by muse, mutect2, varscan2
- SYT9 | c.639G>A p.G213= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV59625090; called by muse, mutect2
- TAOK3 | c.465A>T p.L155= | Silent (SNP) | VAF 66/158 reads (42%) | called by muse, mutect2, varscan2
- TMIGD2 | c.756C>T p.P252= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs760946706, COSV100010224, COSV56667219; called by muse, mutect2, varscan2
- TSPYL6 | c.1113G>A p.E371= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as rs961412884; called by muse, mutect2, varscan2
- YIPF7 | c.619C>T p.L207= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as rs377377967; called by muse, varscan2
- ZDHHC24 | c.213C>T p.L71= | Silent (SNP) | VAF 129/492 reads (26%) | catalogued as rs1303396141; called by muse, mutect2, varscan2
- ADAD2 | c.418+126A>G | Intron (SNP) | VAF 93/204 reads (46%) | called by muse, mutect2, varscan2
- AGMO | c.1263+58966T>A | Intron (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- ARL15 | c.-13T>C | 5'UTR (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3033G>A | Intron (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- ATAD3B | c.282+1234C>T | Intron (SNP) | VAF 264/446 reads (59%) | catalogued as rs752447428; called by muse, mutect2, varscan2
- CACNB4 | c.148-88210T>C | Intron (SNP) | VAF 17/311 reads (5%) | called by muse, mutect2
- CIDEC | c.*30T>C | 3'UTR (SNP) | VAF 208/420 reads (50%) | called by muse, mutect2, varscan2
- CUX2 | c.63+65760T>C | Intron (SNP) | VAF 124/246 reads (50%) | called by muse, mutect2, varscan2
- DCHS2 | n.2010T>C | RNA (SNP) | VAF 68/117 reads (58%) | called by muse, mutect2, varscan2
- EVA1B | chr1:36327876 C>G | 5'Flank (SNP) | VAF 12/188 reads (6%) | catalogued as rs1248576102; called by muse, mutect2
- FAM183BP | n.1184G>A | RNA (SNP) | VAF 17/322 reads (5%) | catalogued as rs561171468; called by muse, mutect2
- FCGBP | c.*4G>C | 3'UTR (SNP) | VAF 109/254 reads (43%) | called by muse, mutect2, varscan2
- GPR161 | c.-139+814G>T | Intron (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100648567; called by muse, mutect2, varscan2
- IGSF22 | c.*300G>A | 3'UTR (SNP) | VAF 68/157 reads (43%) | catalogued as rs1057009437; called by muse, mutect2, varscan2
- JMJD1C | c.-105G>A | 5'UTR (SNP) | VAF 51/188 reads (27%) | called by muse, mutect2, varscan2
- KAT5 | c.13-19C>A | Intron (SNP) | VAF 62/88 reads (70%) | called by muse, mutect2, varscan2
- KIRREL1 | c.-23C>T | 5'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- LY6G6E | c.*5C>T | 3'UTR (SNP) | VAF 54/108 reads (50%) | catalogued as rs531755764, COSV101011702; called by muse, mutect2, varscan2
- MORN4 | c.-76A>G | 5'UTR (SNP) | VAF 157/339 reads (46%) | called by muse, mutect2, varscan2
- MPZ | c.645+31G>A | Intron (SNP) | VAF 99/419 reads (24%) | called by muse, mutect2, varscan2
- NORAD | n.565G>A | RNA (SNP) | VAF 24/316 reads (8%) | called by muse, mutect2
- NPAS3 | chr14:32934925 G>C | 5'Flank (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2
- NUP214 | c.2541-22C>A | Intron (SNP) | VAF 27/180 reads (15%) | called by muse, mutect2
- OGFOD3 | c.824-1894G>A | Intron (SNP) | VAF 59/142 reads (42%) | catalogued as rs779487314; called by muse, mutect2, varscan2
- OR52B1P | n.405T>G | RNA (SNP) | VAF 68/122 reads (56%) | catalogued as rs1465839688; called by muse, mutect2, varscan2
- PPOX | c.869-33G>T | Intron (SNP) | VAF 25/367 reads (7%) | called by muse, mutect2
- SPANXB1 | c.-62C>A | 5'UTR (SNP) | VAF 113/624 reads (18%) | called by muse, mutect2, varscan2
- SPATA21 | c.35-3221C>T | Intron (SNP) | VAF 76/108 reads (70%) | catalogued as rs945821643; called by muse, mutect2, varscan2
- TNRC18 | chr7:5427721 C>A | 5'Flank (SNP) | VAF 16/214 reads (7%) | catalogued as rs1218748067; called by muse, mutect2
- WDR55 | c.*2145_*2147dup | 3'UTR (INS) | VAF 82/194 reads (42%) | called by mutect2, pindel, varscan2
- ZDHHC11 | c.784+103C>T | Intron (SNP) | VAF 53/171 reads (31%) | catalogued as rs571252154; called by muse, mutect2, varscan2
